Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A729, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A729-06A (Metastatic).

[page 1 of 2]
DERMATOPATHOLOGY

Case Number:

110-0-13

Melanoma, malignant
8720/3

Site Inguinal lymph
node c7.4
JW 8/11/13

Diagnosis:

A: Lymph nodes, right superficial inguinal, removal

-Metastatic melanoma involving 1 out of 22 lymph nodes, with the largest diameter measuring 5.5 cm grossly (1/22)

-Extracapsular extension is present

-Block A1 will be sent for BRAF testing

Updated AJCC Staging: pT2a pN1b pMx

B: Lymph nodes, right external iliac, removal

-No evidence of melanoma in 7 lymph nodes (0/7)

C: Lymph nodes, right external iliac, removal

-No evidence of melanoma in 4 lymph nodes (0/4)

D: Lymph nodes, right internal iliac and obturator, removal

-No evidence of melanoma in 9 lymph nodes (0/9)

E: Lymph node, right node of Cloquet, removal

-No evidence of melanoma or lymph node tissue identified

-The entire specimen was submitted and examined microscopically

F: Lymph nodes, right common iliac nodes, removal

-No evidence of melanoma in 8 lymph nodes (0/8)

G: Right posterior calf, excision

-Biopsy site changes with no residual melanoma

Clinical History:

year-old female with melanoma

Gross Description:

A: The specimen was received labeled with the patient's name and measured 14 x 9 x 4 cm. There is a 5.5 x 4.5 x 3.5 cm tan-white mass. Fresh tissue from this mass is taken by tissue procurement. The fibrofatty specimen is serially sectioned and then placed in Lymph node candidates are identified and submitted as A1-10 with blocks A1 and A2 contained representative sections of the mass. Tissue remains in formalin.

[page 2 of 2]
B: The specimen was received labeled with the patient' s name and measured 5.5 x 5 x 2 cm. The tissue is entirely submitted as B1-8,

C: The specimen was received labeled with the patient' s name and measured 4 x 4 x 2 cm. The tissue is entirely submitted as C1-6,

D: The specimen was received labeled with the patient' s name and measured 6 x 3 x 1.5 cm. The tissue is entirely submitted as D1-6,

E: The specimen was received labeled with the patient' s name and measured 2.1 x 2 x 1.4 cm. The tissue is entirely submitted as E1-3,

F: The specimen was received labeled with the patient' s name and measured 3 x 1.5 x 1.4 cm. The tissue is entirely submitted as F1-3,

G: The specimen bears a long suture indicating lateral and a short suture indicating superior and measures 32 x 31 x 10 mm. Viewing the specimen with the short suture at the 12:00 position and the long suture at the 3:00 position, the margin encompassing the 12:00-3:00 quadrant is inked green, 3:00-6:00 quadrant is inked yellow, 6:00-9:00 quadrant is inked black, and the 9:00-12:00 quadrant is inked orange. Central sections to include the 12:00 and 6:00 margins are submitted as block 1 and 2. Perpendicular sections of the 12:00-3:00 margin are submitted as block 3 and 4, 3:00-6:00 margin as block 5 and 6, 6:00-9:00 margin as block 7 and 8, and 9:00-12:00 margin as block 9 and 10,

Light Microscopy:

Light microscopic examination is performed by Dr. S100 and Melan A are positive in block A1 thereby supporting the diagnosis of metastatic melanoma.

Source: NCI Genomic Data Commons file b42b847c-6e40-48b1-aab9-d3cfb533ec4e (TCGA-FR-A729.E1B37296-5114-47F3-A48E-2046B7939823.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).